Somatic mutation profile of tumor specimen 0DT7X2 from CCDI case PBCHMC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain stem; Age at diagnosis: 6.0 years (2,184 days).
Specimen 0DT7X2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f59059cf-7f76-4e66-9bf1-97bbf885cf99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DT7WS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/637d80f9-f8dd-4bc9-9847-9b8f41ee80e7

The open-access MAF lists 26 somatic variants for this specimen: 17 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 5, Frame Shift Del 2, Intron 2, 3'UTR 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 285/779 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 177/580 reads (31%) | hotspot (GDC flag); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATMIN | c.2302A>G p.M768V | Missense Mutation (SNP) | VAF 197/768 reads (26%) | SIFT tolerated (0.7); PolyPhen benign (0.009); catalogued as rs978483581; called by muse, mutect2, varscan2
- CHAMP1 | c.1373C>T p.T458I | Missense Mutation (SNP) | VAF 174/637 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as rs782647633; called by muse, mutect2, varscan2
- EGR2 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.07); catalogued as rs779781939; called by muse, mutect2, varscan2
- F5 | c.4559C>T p.T1520I | Missense Mutation (SNP) | VAF 88/1572 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as rs1373826993; called by muse, mutect2
- MCM2 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 111/409 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1202619807; called by muse, mutect2, varscan2
- MUC17 | c.3157A>G p.M1053V | Missense Mutation (SNP) | VAF 122/418 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs759411637, COSV60287768, COSV60290780; called by mutect2, varscan2
- TENT5C | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 208/737 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as rs1278971822; called by muse, mutect2, varscan2
- ABL2 | c.2349_2350del p.T784Ifs*12 (on ENST00000502732 / NM_007314.4; = p.T769Ifs*12 on NM_005158.5) | Frame Shift Del (DEL) | VAF 137/602 reads (23%) | called by mutect2, varscan2
- CYP4F12 | c.571A>G p.M191V | Missense Mutation (SNP) | VAF 230/854 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.087); called by muse, mutect2
- DSC1 | c.136C>A p.L46I | Missense Mutation (SNP) | VAF 256/863 reads (30%) | SIFT tolerated (0.33); PolyPhen benign (0.015); called by mutect2, varscan2
- GRM8 | c.1768del p.V590Lfs*12 | Frame Shift Del (DEL) | VAF 118/658 reads (18%) | called by mutect2, varscan2
- KIAA1109 | c.13801C>G p.P4601A | Missense Mutation (SNP) | VAF 149/892 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRC66 | c.1888A>T p.I630F | Missense Mutation (SNP) | VAF 188/652 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.076); called by mutect2, varscan2
- OR11H6 | c.964G>A p.V322I | Missense Mutation (SNP) | VAF 322/997 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- VIPR1 | c.688T>A p.F230I | Missense Mutation (SNP) | VAF 37/579 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ETV4 | c.1248C>T p.Y416= | Silent (SNP) | VAF 100/342 reads (29%) | catalogued as rs556620242; called by muse, mutect2, varscan2
- EYS | c.51T>C p.S17= | Silent (SNP) | VAF 293/992 reads (30%) | catalogued as rs1177893706, COSV100675603, COSV60994080; called by muse, varscan2
- SLC22A13 | c.1485G>C p.L495= | Silent (SNP) | VAF 33/288 reads (11%) | catalogued as rs1334034788; called by muse, mutect2, varscan2
- UBA7 | c.1446C>T p.L482= | Silent (SNP) | VAF 19/545 reads (3%) | called by muse, mutect2
- ZNF266 | c.366C>A p.T122= | Silent (SNP) | VAF 176/647 reads (27%) | called by mutect2, varscan2
- MTHFR | c.*1852G>C | 3'UTR (SNP) | VAF 29/71 reads (41%) | catalogued as rs114290429; called by muse, mutect2, varscan2
- PSMD1 | c.2116-45C>T | Intron (SNP) | VAF 131/579 reads (23%) | called by muse, mutect2, varscan2
- VSTM1 | c.-60C>T | 5'UTR (SNP) | VAF 46/137 reads (34%) | called by muse, mutect2, varscan2
- ZFPL1 | c.746+22G>A | Intron (SNP) | VAF 50/325 reads (15%) | catalogued as rs774786874; called by muse, mutect2, varscan2
